Somatic mutation profile of tumor specimen TCGA-55-7815-01A (aliquot TCGA-55-7815-01A-11D-2167-08) from TCGA case TCGA-55-7815, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 77.0 years (28,119 days).
Specimen TCGA-55-7815-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a56f81a6-76fa-4e54-89ef-08e340de73f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7815-10A (Blood Derived Normal), aliquot TCGA-55-7815-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c3fc5a7-5dd1-4eb5-bce8-bafa31ed0ae2

The open-access MAF lists 158 somatic variants for this specimen: 116 protein-altering or splice-affecting, 35 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 35, Nonsense Mutation 6, Intron 4, 3'Flank 2, 3'UTR 1, In Frame Del 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.2308G>T p.E770* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as rs1555075721, COSV53724876; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCF3 | c.1010C>G p.A337G | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53051241; called by muse, mutect2, varscan2
- ACVR1 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55116160; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1160C>A p.A387E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV52808055, COSV52818004; called by muse, mutect2, varscan2
- ADNP2 | c.2612G>T p.G871V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.107); catalogued as COSV51536079; called by muse, mutect2, varscan2
- AGBL5 | c.2635C>A p.P879T | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV64078998, COSV64079841; called by muse, mutect2, varscan2
- ALPK2 | c.5441A>T p.H1814L | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV64490082; called by muse, mutect2, varscan2
- AP3D1 | c.2392C>T p.P798S | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100642467; called by muse, mutect2
- ARHGEF11 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs777668643, COSV63810222; called by muse, mutect2
- ARID1A | c.3677A>G p.Y1226C | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs200814245, COSV61371264; called by muse, mutect2, varscan2
- ASXL3 | c.5140A>C p.S1714R | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.143); catalogued as rs568504492, COSV52456486; called by muse, mutect2, varscan2
- AWAT1 | c.254C>A p.T85K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65738124, COSV65738782; called by muse, mutect2, varscan2
- BIRC6 | c.1902C>G p.S634R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV70195325; called by muse, mutect2, varscan2
- CAPN3 | c.1002C>G p.H334Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM970214, COSV58819086; called by muse, mutect2, varscan2
- CATSPER4 | c.432G>T p.W144C | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58792181; called by muse, mutect2, varscan2
- CCNT1 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV56063048; called by muse, mutect2, varscan2
- CDH23 | c.5477G>A p.R1826Q | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.939); catalogued as rs780097768, COSV56445883; called by muse, mutect2, varscan2
- CHRM3 | c.294G>T p.Q98H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55079350; called by muse, mutect2, varscan2
- CLVS1 | c.555C>A p.D185E | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57970137; called by muse, mutect2, varscan2
- COL5A2 | c.3194G>T p.G1065V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66406846; called by muse, mutect2, varscan2
- CST4 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV54149124; called by muse, mutect2, varscan2
- CWH43 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.107); catalogued as COSV56935687; called by muse, mutect2
- CX3CR1 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64192931; called by muse, mutect2, varscan2
- DCAF4L2 | c.128G>T p.C43F | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV60476294; called by muse, mutect2, varscan2
- DDX24 | c.1900G>T p.A634S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV58211727; called by muse, mutect2, varscan2
- DMBT1 | c.2513G>A p.R838Q | Missense Mutation (SNP) | VAF 56/453 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.04); catalogued as rs561523976, COSV57533504; called by muse, mutect2, varscan2
- DSG4 | c.2189C>G p.S730W | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1260703500, COSV57388088; called by muse, mutect2, varscan2
- EPHA5 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV56629814; called by muse, mutect2, varscan2
- FAM120A | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.933); catalogued as rs757664592, COSV52900957; called by muse, mutect2, varscan2
- FAM168A | c.131A>T p.N44I | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.102); catalogued as COSV50356673, COSV99291508; called by muse, mutect2, varscan2
- FAM47B | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV61452353, COSV61453640; called by muse, mutect2, varscan2
- GJA5 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs782745264, COSV54782815, COSV54783240; called by muse, mutect2, varscan2
- GPHA2 | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1268727539, COSV51209643; called by muse, mutect2, varscan2
- GTPBP3 | c.975-1G>T p.X325_splice | Splice Site (SNP) | VAF 14/65 reads (22%) | catalogued as COSV61412534; called by muse, mutect2, varscan2
- GUCY2D | c.1484A>G p.Q495R | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV54694331; called by muse, mutect2, varscan2
- HAMP | c.182C>A p.T61N | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV55885199; called by muse, mutect2
- HEPH | c.3194G>C p.R1065P (on ENST00000343002; = p.R798P on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.585); catalogued as COSV57958684, COSV57959706; called by muse, mutect2, varscan2
- HLA-C | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66110130; called by muse, varscan2
- HUS1B | c.571C>G p.L191V | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV57860951; called by muse, mutect2, varscan2
- IGHV3-38 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 63/265 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.579); catalogued as rs372410193; called by muse, mutect2, varscan2
- IL18RAP | c.995G>C p.R332P | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV51823765; called by muse, mutect2, varscan2
- IL1RL2 | c.800A>G p.N267S | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs1282187332, COSV51812794; called by muse, mutect2, varscan2
- IL4R | c.2011C>T p.P671S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as COSV50138145; called by muse, mutect2, varscan2
- KEAP1 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV50260766, COSV50261366; called by muse, mutect2, varscan2
- KLK7 | c.469G>T p.V157L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV58343874; called by muse, mutect2
- LEMD2 | c.29G>C p.R10P | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.943); catalogued as COSV53393121; called by muse, mutect2, varscan2
- MITF | c.511G>T p.V171L (on ENST00000448226 / NM_006722.3; = p.V65L on NM_000248.4) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.022); catalogued as COSV100096646; called by muse, mutect2, varscan2
- MORC1 | c.154G>T p.V52L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.345); catalogued as COSV51713531; called by muse, mutect2
- MPDZ | c.1238G>T p.S413I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV59935325; called by muse, mutect2, varscan2
- MRPS18C | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as COSV55024048; called by muse, mutect2, varscan2
- MYH7 | c.4453A>T p.K1485* | Nonsense Mutation (SNP) | VAF 18/202 reads (9%) | catalogued as COSV100805830; called by muse, mutect2
- NAT8 | c.221T>A p.L74Q | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV55542150; called by muse, mutect2, varscan2
- NCALD | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.671); catalogued as rs771489034, COSV55270888; called by muse, mutect2, varscan2
- NCKAP5 | c.5506G>A p.G1836R | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs368736527; called by muse, mutect2
- NOD2 | c.2726A>T p.N909I | Missense Mutation (SNP) | VAF 114/505 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56048173; called by muse, mutect2, varscan2
- OCA2 | c.1054A>T p.R352* | Nonsense Mutation (SNP) | VAF 29/168 reads (17%) | catalogued as COSV62337920; called by muse, mutect2, varscan2
- OR1Q1 | c.245T>A p.L82Q | Missense Mutation (SNP) | VAF 42/241 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52917156; called by muse, mutect2, varscan2
- OR4L1 | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 20/249 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV100235854, COSV59848845; called by muse, mutect2
- OR5AS1 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs780515543, COSV57980629, COSV57982623; called by mutect2, varscan2
- OR6F1 | c.696T>A p.S232R | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV57466706; called by muse, mutect2, varscan2
- OR8D4 | c.499T>A p.S167T | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.031); catalogued as COSV58429372; called by muse, mutect2
- OR8H1 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs142532321, CM125354, COSV57292940, COSV57293327; called by muse, mutect2, varscan2
- PCDHGA1 | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.502); catalogued as COSV65294825, COSV65298907; called by muse, mutect2, varscan2
- PHF20 | c.2356G>T p.G786W | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV64974614; called by muse, mutect2, varscan2
- PIK3C2G | c.3867A>C p.Q1289H (on ENST00000676171; = p.Q1248H on NM_004570.5) | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV56796203; called by muse, mutect2
- PLSCR5 | c.587G>A p.C196Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs958037679, COSV71648919; called by muse, mutect2
- PMFBP1 | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 52/145 reads (36%) | catalogued as COSV52820416; called by muse, mutect2, varscan2
- PPARG | c.553A>G p.K185E (on ENST00000287820 / NM_015869.5; = p.K155E on NM_005037.7) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as COSV55140881; called by muse, mutect2, varscan2
- PPM1D | c.788T>C p.I263T | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as COSV59954205; called by muse, mutect2
- PTPRT | c.2044G>T p.G682C | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61958773; called by muse, mutect2, varscan2
- RABGGTB | c.11C>G p.P4R | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.157); catalogued as COSV60636827; called by muse, varscan2
- RAG2 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 7/87 reads (8%) | catalogued as CM108348, COSV57556259; called by muse, mutect2
- RBFOX1 | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as COSV60944421; called by muse, mutect2, varscan2
- RDH13 | c.940G>T p.A314S (on ENST00000415061 / NM_001145971.2; = p.A243S on NM_138412.4) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs761854926, COSV52559579; called by muse, mutect2, varscan2
- RFX1 | c.2206G>T p.V736L | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV54327506; called by muse, mutect2, varscan2
- RNLS | c.134C>G p.T45R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59290204; called by muse, mutect2
- RYR2 | c.12169C>G p.H4057D | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.306); catalogued as COSV63659365; called by muse, mutect2
- SAMD9L | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV59079248, COSV59081955; called by muse, mutect2, varscan2
- SBSN | c.19G>T p.V7F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV71733020; called by muse, mutect2, varscan2
- SERPINA6 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100448195, COSV100448324; called by muse, mutect2
- SHOX | c.172G>C p.D58H | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.191); catalogued as COSV61860042; called by muse, mutect2, varscan2
- SLC17A4 | c.631G>T p.G211W | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64955494; called by muse, mutect2, varscan2
- SLC27A4 | c.1733G>T p.R578L | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV55958589, COSV55958841; called by muse, mutect2, varscan2
- SLC28A3 | c.1100G>C p.G367A | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1458900771, COSV66151994; called by muse, mutect2, varscan2
- SLC6A19 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100443308; called by muse, mutect2
- SLIT1 | c.1557T>A p.C519* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as COSV56581889; called by muse, mutect2, varscan2
- SLK | c.2797G>A p.V933M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV59823512; called by muse, mutect2
- SMARCA2 | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV61804497; called by muse, mutect2, varscan2
- SPATA31E1 | c.1505A>T p.Q502L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV57789403; called by muse, mutect2, varscan2
- SPATA7 | c.1040A>T p.Q347L | Missense Mutation (SNP) | VAF 86/249 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.049); catalogued as COSV50415872; called by muse, mutect2, varscan2
- SPON1 | c.658C>A p.H220N | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV59957339; called by muse, mutect2, varscan2
- STING1 | c.851G>T p.R284M | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58172001; called by muse, mutect2, varscan2
- SUFU | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV64013760, COSV64014306; called by muse, mutect2
- SYNE2 | c.2566G>C p.E856Q | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1403336820, COSV59939044; called by muse, mutect2, varscan2
- TDRD6 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373561239, COSV60173778; called by muse, mutect2, varscan2
- TNS2 | c.2888G>T p.G963V (on ENST00000314250 / NM_170754.4; = p.G973V on NM_015319.2) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100036603; called by muse, mutect2, varscan2
- TPSD1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.162); catalogued as rs1253055705, COSV52973935; called by muse, mutect2, varscan2
- TRIM46 | c.1018C>A p.Q340K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55278119; called by muse, mutect2, varscan2
- TTLL7 | c.473T>C p.I158T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV53081185; called by muse, mutect2, varscan2
- TTLL7 | c.272A>T p.N91I | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV53081193; called by muse, mutect2, varscan2
- UBA1 | c.789G>T p.Q263H | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1184192290, COSV60111115; called by muse, mutect2, varscan2
- UNKL | c.341G>C p.R114P | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs965586739, COSV57018671; called by muse, mutect2, varscan2
- USP17L2 | c.1297A>C p.T433P | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61555432; called by muse, mutect2, varscan2
- WIPF3 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs201706623; called by mutect2, varscan2
- WNT5B | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV60197332; called by muse, mutect2, varscan2
- WNT8B | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59324498; called by muse, mutect2
- ZFHX4 | c.504C>A p.D168E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as COSV50481719; called by muse, mutect2, varscan2
- ZNF506 | c.229A>T p.M77L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1209669261, COSV71354198; called by muse, mutect2, varscan2
- ZNF610 | c.436T>A p.Y146N | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV58343428; called by muse, mutect2, varscan2
- ZNF98 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.458); catalogued as rs1300909397, COSV63334131; called by mutect2, varscan2
- ABCA13 | c.13847C>T p.P4616L | Missense Mutation (SNP) | VAF 2/18 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DPF2 | c.1107_1121del p.W369_L373del | In Frame Del (DEL) | VAF 16/140 reads (11%) | called by mutect2, pindel
- RBM10 | c.1705_1709del p.V569Yfs*6 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | called by mutect2, pindel, varscan2
- SLC26A3 | c.533C>A p.A178E | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- SPATA31A1 | c.3953T>A p.V1318D | Missense Mutation (SNP) | VAF 64/306 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADGRG3 | c.946C>T p.L316= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV59650065; called by muse, mutect2, varscan2
- ALPI | c.1281C>T p.D427= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs779857444, COSV55013324; called by muse, mutect2, varscan2
- ASMT | c.408C>A p.G136= | Silent (SNP) | VAF 26/221 reads (12%) | catalogued as rs770366013, COSV67109499; called by muse, mutect2, varscan2
- BLZF1 | c.738T>C p.A246= | Silent (SNP) | VAF 4/90 reads (4%) | catalogued as COSV61392652; called by muse, mutect2
- CCDC150 | c.2139A>T p.S713= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV55871487; called by muse, mutect2, varscan2
- CDAN1 | c.2604C>T p.F868= | Silent (SNP) | VAF 16/148 reads (11%) | catalogued as rs767340780, COSV62330685; called by muse, mutect2, varscan2
- CDK5R2 | c.1068C>A p.A356= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV56935462; called by muse, mutect2
- CSNK1A1L | c.243G>A p.Q81= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV65789300; called by muse, mutect2, varscan2
- CTBP1 | c.1053C>T p.V351= | Silent (SNP) | VAF 9/127 reads (7%) | catalogued as COSV52071700; called by muse, mutect2
- EEF1A2 | c.798G>T p.R266= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV53204630; called by muse, mutect2, varscan2
- ETV1 | c.696C>T p.H232= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs577222571, COSV54136412; called by muse, mutect2, varscan2
- FLG | c.10746C>T p.H3582= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs75279506; called by muse, mutect2, varscan2
- FLG | c.6858C>T p.H2286= | Silent (SNP) | VAF 69/983 reads (7%) | catalogued as rs141571186, COSV64236077; called by muse, mutect2
- LRRN3 | c.18C>A p.L6= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV57817461, COSV57823147; called by muse, mutect2, varscan2
- MITF | c.510G>T p.P170= (on ENST00000448226 / NM_006722.3; = p.P64= on NM_000248.4) | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV100096640; called by muse, mutect2, varscan2
- MYH3 | c.3480G>C p.T1160= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV56860625; called by muse, mutect2, varscan2
- MYO7B | c.4168C>T p.L1390= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs183041806, COSV67344282; called by muse, mutect2, varscan2
- NOL8 | c.1026A>G p.K342= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV62633984; called by muse, mutect2, varscan2
- OR14C36 | c.534C>T p.D178= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV58600424; called by muse, mutect2, varscan2
- OR52A1 | c.621C>T p.F207= | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as COSV61091933; called by muse, mutect2, varscan2
- OR7C2 | c.912C>A p.L304= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV99934444; called by muse, mutect2
- OSBPL5 | c.1170C>A p.P390= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV55139245; called by muse, mutect2, varscan2
- PARP14 | c.4578C>A p.S1526= | Silent (SNP) | VAF 49/174 reads (28%) | catalogued as COSV71734075; called by muse, mutect2, varscan2
- PCDHGA9 | c.2073C>G p.L691= | Silent (SNP) | VAF 35/153 reads (23%) | catalogued as COSV53895063; called by muse, mutect2, varscan2
- PDGFRB | c.2850C>A p.P950= | Silent (SNP) | VAF 23/188 reads (12%) | catalogued as COSV55800432, COSV55807570; called by muse, mutect2, varscan2
- PIK3R1 | c.1591T>C p.L531= (on ENST00000521381 / NM_181523.3; = p.L261= on NM_181504.4) | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs778058990, COSV57123278; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1401T>C p.A467= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV57962333; called by muse, mutect2, varscan2
- REPS1 | c.2157A>G p.E719= (on ENST00000450536 / NM_001286611.2; = p.E718= on NM_031922.4) | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV57808506; called by muse, mutect2, varscan2
- SEL1L2 | c.1290C>A p.A430= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV53147671; called by muse, mutect2, varscan2
- SH2D4B | c.219G>T p.G73= | Silent (SNP) | VAF 26/145 reads (18%) | catalogued as COSV57892424; called by muse, mutect2, varscan2
- SHANK2 | c.5190C>T p.T1730= | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as rs566820305, COSV53584755; called by muse, mutect2, varscan2
- SLC7A13 | c.318G>T p.G106= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV52532281; called by muse, mutect2, varscan2
- SMOC1 | c.1029G>T p.A343= | Silent (SNP) | VAF 11/120 reads (9%) | catalogued as COSV62759416; called by muse, mutect2, varscan2
- VCAM1 | c.114G>A p.Q38= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV54117655; called by muse, mutect2, varscan2
- ZNF423 | c.957C>A p.L319= (on ENST00000563137 / NM_001379286.1; = p.L311= on NM_015069.4) | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV52176036; called by muse, mutect2, varscan2
- ANK1 | c.5395-1155G>T | Intron (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99224447; called by muse, mutect2
- DTWD2 | c.218+13693A>G | Intron (SNP) | VAF 8/104 reads (8%) | catalogued as rs765671802; called by muse, mutect2
- FHL2 | c.-76+38C>A | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as rs775482193, COSV100362849; called by muse, mutect2, varscan2
- PCOLCE2 | c.*2A>C | 3'UTR (SNP) | VAF 16/81 reads (20%) | catalogued as COSV99930456; called by muse, mutect2, varscan2
- PPP2R2C | c.71-710G>T | Intron (SNP) | VAF 13/103 reads (13%) | catalogued as COSV100066129; called by muse, mutect2, varscan2
- SNRPN | chr15:24980026 G>C | 3'Flank (SNP) | VAF 2/14 reads (14%) | called by muse, mutect2
- SNRPN | chr15:24980027 A>T | 3'Flank (SNP) | VAF 2/14 reads (14%) | called by muse, mutect2
